Gene-level copy-number profile of tumor specimen HCM-STAN-1109-D13-01A from HCMI case HCM-STAN-1109-D13, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage 0.
Specimen HCM-STAN-1109-D13-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6cc23703-dfb8-40e6-aa98-3f651a192115.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-1109-D13-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/ed7106e3-1458-43df-a882-610bfe746ae2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 4,218; copy number 2: 54,660; copy number 3: 16; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:668,105–711,277, 11 genes (within-gene range 0–2): RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,369. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
